Gene-level copy-number profile of tumor specimen TCGA-EA-A3QD-01A from TCGA case TCGA-EA-A3QD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 59.3 years (21,655 days).
Specimen TCGA-EA-A3QD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.62a4ad97-9432-45d6-a81b-78d84d58fac6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EA-A3QD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a615ddac-e487-43e1-a86f-7319985805c5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,426; copy number 2: 45,159; copy number 3: 8,850; copy number 4: 889; copy number 5: 131; copy number 6: 35; copy number 7: 119; copy number 11: 28; copy number 17: 2; copy number 24: 180; copy number 31: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EA-A3QD-01A-32D-A22W-01): tumor purity 0.53, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 461 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,578,473–127,636,867, 1 gene, copy number 31 (within-gene range 2–31): AC104370.1.
- chr9:14,475–15,544,294, 209 genes, copy number 11–24 (broad region; genes not listed).
- chr9:15,588,355–15,588,615, 1 gene, copy number 24: HMGN2P16.
- chr11:81,821,272–82,718,299, 1 gene, copy number 7 (within-gene range 2–7): MIR4300HG.
- chr11:82,603,529–85,627,922, 37 genes, copy number 7 (within-gene range 4–7): AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2, DLG2, DLG2-AS2, AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1.
- chr13:107,788,342–114,337,626, 131 genes, copy number 5 (broad region; genes not listed).
- chr20:32,983,773–35,278,131, 81 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,426. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
